Gene-level copy-number profile of tumor specimen C3N-02143-03 from CPTAC case C3N-02143, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G2.
Specimen C3N-02143-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e08a1b2-d510-4c18-acee-2c314653d474.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02143-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/51233093-315d-4004-8044-72cc26b6eff3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 12,546; copy number 2: 40,880; copy number 3: 4,328; copy number 4: 683; copy number 5: 137; copy number 6: 84; copy number 7: 98; copy number 9: 29; copy number 13: 5; copy number 15: 1; copy number 19: 7; copy number 26: 23.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:46,109,621–46,273,557, 2 genes: AGAP7P, ANTXRLP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 365 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:195,996,262–196,027,694, 2 genes, copy number 5 (within-gene range 2–5): AC024937.3, AC024937.2.
- chr5:441,498–2,119,926, 58 genes, copy number 5–9: EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, MIR4277, AC112176.1, MRPL36, NDUFS6, AC025183.1, LINC02116, AC025183.2, IRX4, IRX4-AS1, CTD-2194D22.4, AC126768.3, AC124852.1, AC126768.1, AC126768.2.
- chr5:10,337,277–12,574,637, 27 genes, copy number 5: Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P, AC106771.1.
- chr5:14,143,342–14,699,850, 8 genes, copy number 6: TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN.
- chr5:33,936,386–34,958,964, 23 genes, copy number 5: RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21.
- chr5:36,246,913–37,249,421, 13 genes, copy number 5 (within-gene range 3–5): RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2.
- chr5:37,249,026–37,252,617, 1 gene, copy number 5: AC025449.2.
- chr7:52,165,235–55,862,755, 56 genes, copy number 5–26: AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr7:62,275,361–62,275,678, 1 gene, copy number 15: AC128676.1.
- chr7:65,773,620–65,814,775, 2 genes, copy number 9: GTF2IP5, RNU6-912P.
- chr8:87,540,835–87,755,718, 1 gene, copy number 5 (within-gene range 2–5): AF121898.1.
- chr8:87,788,562–98,036,724, 150 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:125,648,327–126,008,930, 1 gene, copy number 6 (within-gene range 4–6): AC016074.2.
- chr8:125,859,721–126,558,478, 13 genes, copy number 6 (within-gene range 4–6): LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2.
- chr8:131,129,761–132,111,159, 8 genes, copy number 5: AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1.
- chr8:137,105,352–137,105,458, 1 gene, copy number 6: RNU6-144P.

Autosomal genes at a single copy (total copy number 1): 10,582. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
